Surgical pathology report (de-identified scan), TCGA case TCGA-85-8666, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8666-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED] Case ID [REDACTED]		Microscopic Description	Diagnosis Details
[REDACTED]	Lung of 21 x 16 cm with the tumour of the upper lobe bronchus, 4 cm in size, grey-pinkish coloured.	Moderately differentiated squamous carcinoma, G2. Six aortic window lymph nodes, two bifurcational and three bronchopulmonary - anthracosis.	Tumor Features: Unknown, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 2 of 3]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Pneumonectomy Tumor site: Lung Tumor size: 4 x 0 x 0 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 0/11 positive for metastasis (Aortic window, bifurcational, bronchopulmonary 0/11) Lymphatic invasion: Not specified Venous invasion: Absent Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified

ica ID

[page 3 of 3]
Excision date

████████████████████

Source: NCI Genomic Data Commons file 55876f39-1a53-47e7-b285-84901a281051 (TCGA-85-8666.C9EC1868-C91E-4778-8411-FD8AD272E453.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).